Somatic mutation profile of tumor specimen MMRF_1690_1_BM_CD138pos (aliquot MMRF_1690_1_BM_CD138pos_T1_KBS5U_L06419) from MMRF case MMRF_1690, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.8 years (21,110 days).
Specimen MMRF_1690_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 008bf2f2-1947-47b1-862b-9328e4ca1378.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1690_3_PB_Whole (Blood Derived Normal), aliquot MMRF_1690_3_PB_Whole_C1_KBS5U_L06466; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf5fdfdf-9e47-4b07-a55d-0eac26a8dde8

The open-access MAF lists 101 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 22, Silent 16, Intron 14, 3'Flank 5, 5'Flank 2, 5'UTR 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 58/71 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, varscan2
- AQP2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs755694590, CM973106; called by muse, mutect2, varscan2
- ARHGAP22 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs138535081; called by muse, mutect2, varscan2
- ATF4 | c.791del p.P264Lfs*6 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as COSV100307880; called by mutect2, pindel, varscan2
- CDH4 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs895024295, COSV100848575, COSV64661310; called by muse, mutect2, varscan2
- CRB1 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV66333556; called by muse, mutect2
- FLG | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV64237476, COSV64246276; called by muse, mutect2
- FXR2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1345315697; called by muse, mutect2, varscan2
- GRAMD1C | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1309030269; called by muse, mutect2, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- IGHV2-70 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGLL5 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs560170702; called by muse, varscan2
- IGLV3-1 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs369545397; called by muse, varscan2
- IGLV3-1 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs550143178; called by muse, varscan2
- IGLV3-1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs61736462; called by muse, varscan2
- KSR2 | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749644102, COSV56674344; called by muse, mutect2, varscan2
- MYH14 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 137/283 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs756240699, COSV51810629, COSV99224785; called by muse, mutect2, varscan2
- PABPC4 | c.1009T>C p.F337L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100790872; called by muse, mutect2, varscan2
- PCDHA3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63538638; called by muse, mutect2, varscan2
- SALL4 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1448426581, COSV53849776; called by muse, mutect2, varscan2
- SCLT1 | c.327dup p.L110Ifs*13 | Frame Shift Ins (INS) | VAF 36/104 reads (35%) | catalogued as rs772185859; called by mutect2, varscan2
- TIFAB | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs780767266, COSV72345859; called by muse, mutect2, varscan2
- TMEM175 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs577842900; called by muse, mutect2, varscan2
- ARFGEF2 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- BCL11B | c.2437G>A p.V813M (on ENST00000357195 / NM_001282237.2; = p.V742M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMT2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA1 | c.4723C>A p.P1575T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ERI3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GABRB2 | c.1125G>C p.L375F | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC6 | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- IGHJ5 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 22/29 reads (76%) | PolyPhen benign (0.005); called by muse, varscan2
- INSRR | c.1100A>C p.Q367P | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KIAA1755 | c.1001A>T p.N334I | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- MMEL1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPS2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.27367A>G p.M9123V | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SLC17A6 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM71 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- ZNF341 | c.1000A>T p.N334Y (on ENST00000375200 / NM_001282935.1; = p.N327Y on NM_032819.4) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALPP | c.576G>A p.S192= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs759755247; called by muse, mutect2, varscan2
- COL9A1 | c.2220A>G p.E740= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs1014687667; called by muse, mutect2, varscan2
- DISP3 | c.414C>T p.R138= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1367340914; called by muse, mutect2, varscan2
- GRAMD1B | c.1851G>A p.L617= | Silent (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.72G>A p.R24= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs571313541; called by muse, varscan2
- MCM7 | c.1035C>T p.Y345= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs761417773, COSV57997177; called by muse, mutect2, varscan2
- NLRP7 | c.183C>T p.T61= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as CD094506; called by muse, mutect2, varscan2
- PCDH19 | c.2505G>A p.V835= (on ENST00000373034 / NM_001184880.2; = p.V788= on NM_020766.3) | Silent (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- PLIN5 | c.273C>T p.S91= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- RAI1 | c.3528G>A p.K1176= | Silent (SNP) | VAF 65/178 reads (37%) | called by muse, mutect2, varscan2
- SERPINE1 | c.150C>T p.S50= | Silent (SNP) | VAF 44/199 reads (22%) | called by muse, mutect2, varscan2
- SLC8A1 | c.2064G>A p.L688= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SLITRK1 | c.1420A>C p.R474= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- THY1 | c.21C>T p.I7= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as rs762262836, COSV99411619; called by muse, mutect2, varscan2
- XKR5 | c.1971C>T p.P657= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ZNF169 | c.1782T>C p.G594= | Silent (SNP) | VAF 42/232 reads (18%) | catalogued as rs751241961; called by muse, mutect2, varscan2
- APBA2 | c.*722C>T | 3'UTR (SNP) | VAF 30/131 reads (23%) | catalogued as rs901009774; called by muse, mutect2, varscan2
- ATP5PF | c.*98T>C | 3'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as rs554635248; called by muse, mutect2, varscan2
- C4orf17 | c.880+392G>T | Intron (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- CEP44 | c.*2843T>G | 3'UTR (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- CIT | c.*1752C>T | 3'UTR (SNP) | VAF 54/104 reads (52%) | catalogued as rs563855886; called by muse, mutect2, varscan2
- CKS1B | c.187+35T>C | Intron (SNP) | VAF 97/219 reads (44%) | called by muse, mutect2, varscan2
- COL21A1 | c.1543-14A>T | Intron (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- CRB1 | c.3878+1703G>T | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- DNAI3 | chr1:85133872 del A | 3'Flank (DEL) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- DYNC1I1 | c.365+5526A>C | Intron (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- EIF1 | c.-105C>T | 5'UTR (SNP) | VAF 18/60 reads (30%) | catalogued as rs527750929; called by muse, varscan2
- EMSY | chr11:76553004 G>A | 3'Flank (SNP) | VAF 44/62 reads (71%) | called by muse, mutect2, varscan2
- FCGR3B | c.*375C>T | 3'UTR (SNP) | VAF 144/463 reads (31%) | called by muse, mutect2
- FUNDC2 | c.*1303_*1307dup | 3'UTR (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- GNG12 | c.*2208G>A | 3'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- IFITM10 | c.*1463C>A | 3'UTR (SNP) | VAF 45/294 reads (15%) | called by muse, mutect2, varscan2
- IPMK | c.*1246A>T | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- KCNK16 | c.*186T>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2267-7517G>C | Intron (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- MARCHF8 | c.*1271C>T | 3'UTR (SNP) | VAF 38/102 reads (37%) | catalogued as rs576396790; called by muse, mutect2, varscan2
- MIR495 | n.49G>A | RNA (SNP) | VAF 7/18 reads (39%) | catalogued as rs775033334; called by muse, mutect2, varscan2
- MS4A4A | chr11:60280550 A>G | 5'Flank (SNP) | VAF 34/83 reads (41%) | called by mutect2, varscan2
- MYOCD | chr17:12763744 G>A | 3'Flank (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- NOS3 | c.1752+1438C>T | Intron (SNP) | VAF 161/310 reads (52%) | catalogued as rs373698468; called by muse, mutect2, varscan2
- OGT | c.532-190G>A | Intron (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- PCDH19 | c.*1866G>T | 3'UTR (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9327+498C>A | Intron (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- POLR3A | c.*988C>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as rs376110690; called by muse, mutect2, varscan2
- PPP1R3D | c.*577C>T | 3'UTR (SNP) | VAF 15/77 reads (19%) | catalogued as rs573931707; called by muse, mutect2, varscan2
- PSD2 | c.*1006C>G | 3'UTR (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- PTK7 | c.1228+612G>A | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- RAMP2 | chr17:42760507 C>G | 5'Flank (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- RHOG | c.*473T>C | 3'UTR (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- RHOJ | c.*1392A>G | 3'UTR (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- RNASEK | c.-94G>A | 5'UTR (SNP) | VAF 18/69 reads (26%) | catalogued as rs1282760324; called by muse, mutect2, varscan2
- RPH3A | c.*996G>C | 3'UTR (SNP) | VAF 46/176 reads (26%) | called by muse, mutect2, varscan2
- RPP40 | c.268+104del | Intron (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- SCFD2 | c.1562-35378G>A | Intron (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- SCRT2 | c.*1581C>T | 3'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1029802805; called by muse, mutect2
- SLC22A25 | c.1071-129A>T | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2
- TAF12 | chr1:28602882 G>A | 3'Flank (SNP) | VAF 3/26 reads (12%) | catalogued as rs972243139; called by muse, mutect2
- TBX5 | c.*758C>A | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- TMEM150A | c.66-109A>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- TNFSF13B | c.*80A>C | 3'UTR (SNP) | VAF 16/30 reads (53%) | catalogued as rs9520837; called by mutect2, varscan2
- UTS2B | chr3:191262887 T>C | 3'Flank (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ZADH2 | c.*5747A>G | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs1357730528; called by mutect2, varscan2
